Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-8001, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-8001-01A (Primary Tumor).

[page 1 of 5]
Patient Results

TCGA - HZ - 8001

Surgical Pathology (Copath)

Final

Path Report

Final

SURGICAL PATHOLOGY REPORT

ACCESSION NO. : [REDACTED]

Final Diagnosis(es):

(A) Liver, biopsy:

1) Minimal mixed portal inflammation.

2) Mild cholestasis.

3) Focal area of dense fibrosis.

4) Negative for malignancy.

(B) Soft tissues, falciform ligament, biopsy:

1) Fibroadipose tissue, consistent with falciform ligament.

2) Negative for malignancy.

(C) Lymph node, hepatoduodenal, biopsy: One lymph node, negative for malignancy (0/1).

(D) Bile duct, margin, biopsy: Negative for malignancy.

(E) Pancreas duct, margin, biopsy: Negative for malignancy.

(F) Soft tissues, middle celiac vein region, biopsy: Positive for metastatic adenocarcinoma.

(G) Head of pancreas, duodenum, stomach, and gallbladder, pancreaticoduodenectomy (Whipple procedure) and cholecystectomy:

1) Invasive ductal adenocarcinoma, moderately differentiated.

2) Tumor size: 3.0 cm.

3) Perineural invasion is present.

4) Anterior and inferior peripancreatic soft tissues are positive for adenocarcinoma.

5) Uncinate, proximal (gastric) and distal (small intestinal) margins,

negative for involvement by adenocarcinoma.

6) Fifteen lymph nodes, negative for malignancy (0/15).

7) Pathologic stage: pT4N0.

8) See Synoptic Report for complete tumor summary.

9) Stomach with no histopathologic abnormality.

10) Duodenal mucosa with no histopathologic abnormality.

11) Gallbladder with chronic cholecystitis.

Synoptic Report:

Specimen:

Head of pancreas.

Duodenum.

Stomach.

Common bile duct.

Gallbladder.

Procedure: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy, cholecystectomy.

[page 2 of 5]
Patient Results

Surgical Pathology (Copath)

Final

Tumor Site: Pancreatic head.

Tumor Size:

Greatest Dimension: 3.0 cm.

Additional Dimensions: 2.0 x 2.0 cm.

Histologic Type: Ductal adenocarcinoma.

Microscopic Tumor Extension:

Tumor invades duodenal wall.

Tumor invades peripancreatic soft tissues (anterior, inferior).

Tumor invades extrapancreatic common bile duct.

Tumor invades other adjacent organs or structures (middle celiac vein).

Margins: Margins uninvolved by invasive carcinoma (proximal, distal, uncinate, bile duct and pancreatic).

Treatment Effect: Not known.

Lymphovascular Invasion: Not identified.

Perineural Invasion: Present.

Pathologic Staging:

Primary Tumor: pT4: Tumor involves the celiac axis or the superior mesenteric artery.

Regional Lymph Nodes: No regional lymph nodes' metastasis.

Number of Lymph Nodes Examined: 16

Number of Lymph Nodes Involved: 0

Distant Metastasis: Not applicable.

Additional Pathologic Findings:

Pancreatic intraepithelial neoplasia (highest grade:

PanIN3).

Chronic pancreatitis.

Comments:

This case has been reviewed and the diagnosis approved by consulting departmental surgical pathology staff.

'The gross description and all microscopic slides have been reviewed and interpreted by the undersigned pathologist'

Specimen(s) Received:

A: Liver biopsy

B: Falciform ligament

C: Hepato-duodenal lymph node

D: Bile duct margin

E: Pancreatic duct margin

F: Middle celiac vein biopsy

G: Gallbladder and small bowel

Clinical History:

Pancreatic cancer.

[page 3 of 5]
Patient Results

Surgical Pathology (Copath)

Final

- (D) Stitch marks true margin.
- (E) Stitch marks true margin.
- (G) Tumor Bank.

Intraoperative Consultation:

Time Received:

Time Reported:

FSA1: Liver biopsy:

Fibrous nodule with thick-walled blood vessels,
negative for malignancy (1 block).

FSD1: Bile duct margin: Negative for in situ or invasive
malignancy (1 block).

FSE1-FSE2: Pancreatic duct margin: Negative for in situ or
invasive malignancy (2 blocks).

FSF1: Middle celiac vein margin: Positive for metastatic
carcinoma (1 block).

Gross Description:

(A) (liver, biopsy) Received fresh from the operating room are multiple red-brown hemorrhagic liver core biopsy fragments measuring 1.0 x 0.2 x 0.2 cm in aggregate. The specimen is entirely used for frozen section and submitted in FSA1.

(B) (falciform ligament) Received in formalin is a yellow-tan fibrofatty tissue measuring 12.5 x 5.0 x 1.0 cm. The specimen is serially sectioned. Serial sectioning does not reveal any gross abnormalities. A representative section is submitted in B1.

(C) (hepatoduodenal lymph node) Received in formalin is a yellow-tan fibrofatty aggregate measuring 2.5 x 1.5 x 0.5 cm. The specimen is serially sectioned and submitted in C1-C2.

(D) (bile duct margin) Received fresh from the operating room is a red-tan hemorrhagic circular bile duct measuring 0.7 x 0.6 x 0.2 cm. The specimen is entirely used for frozen section and submitted in FSD1.

(E) (pancreatic duct margin) Received fresh from the operating room is a red-brown tissue fragment measuring 3.6 x 2.0 x 0.4 cm. The specimen is bisected and entirely submitted for frozen section in FSE1-FSE2.

(F) (middle celiac vein biopsy) Received fresh from the operating room are two tan tissue fragments measuring 1.0 x 0.5 x 0.2 cm in aggregate. The specimen is entirely used for frozen section and submitted in FSF1.

(G) (gallbladder and small bowel) Received fresh from the operating room is a duodenum, stomach, gallbladder and head of

[page 4 of 5]
Patient Results

Surgical Pathology (Copath)

Final

pancreas. The specimen measures 22.0 x 19.0 x 5.5 cm. The stomach measures 8.0 cm in length and 12.0 cm in open circumference. The duodenum measures 18.0 cm in length and 6.5 cm in open circumference. The omental fat near the stomach measures 7.5 cm in length. The gallbladder measures 8.5 x 3.5 x 1.5 cm. The head of the pancreas measures 6.5 x 5.5 x 3.0 cm. The entire outer surface of the head of the pancreas is inked black and a portion of the tissue is given to [REDACTED]. Opening the gallbladder shows red-brown mucoid bile and no calculi. The gallbladder wall is 0.3 cm thick. There is a metal stent in the ampulla. The specimen is opened through the ampulla to the cystic duct and gallbladder and bile duct and part of the common duct mucosa is inked orange. Opening the pancreas from bile duct and ampulla shows a red firm ill-defined mass grossly invading to ampulla, measuring 3.0 x 2.0 x 2.0 cm. This mass is grossly touching the inked anterior and inferior margins and grossly invading the ampulla and bile duct. Dissecting the omental fat reveals multiple lymph nodes ranging in size from 0.5 to 2.0 cm in diameter. Sections are submitted as follows:

- G1 - stomach margin
- G2 - duodenal margin
- G3 - anterior margin, en face
- G4 - superior margin, en face
- G5 - medial margin, en face
- G6 - uncinate margin, en face
- G7 - posterior margin, en face
- G8 - inferior margin, en face
- G9 - gallbladder and cystic duct section
- G10 - bile duct margin
- G11 - section of tumor with bile duct, ampulla and duodenum
- G12 - section of tumor with duodenum
- G13 - section of tumor with normal pancreas
- G14 - section of tumor
- G15 - section of normal pancreas
- G16 - representative section of stomach
- G17 - representative section of duodenum
- G18 - one lymph node, serially sectioned
- G19 - one lymph node, serially sectioned
- G20 - three lymph nodes, bisected
- G21 - three lymph nodes, bisected
- G22 - three lymph nodes, intact

Microscopic Description:

Complete microscopic evaluation has been performed [REDACTED]

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as

[page 5 of 5]
Patient Results

Surgical Pathology (Copath)

Final

analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the Histopathology Laboratory in the Department of Pathology at the

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EGFR(31G7), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26).

Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Source: NCI Genomic Data Commons file d858a1b6-c00b-4632-9fd0-c320ba3aef88 (TCGA-HZ-8001.21A86C40-57A8-43BF-A16E-EBAF0205F33A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).